Somatic mutation profile of tumor specimen TCGA-Z4-AAPF-01A (aliquot TCGA-Z4-AAPF-01A-11D-A38Z-09) from TCGA case TCGA-Z4-AAPF, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Synovial sarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 35.5 years (12,959 days).
Specimen TCGA-Z4-AAPF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bd315ed-7e99-45b7-80dd-307403fc14a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Z4-AAPF-10A (Blood Derived Normal), aliquot TCGA-Z4-AAPF-10A-01D-A38Z-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8c999ba-2197-485c-afd6-b168ac3ac72c

The open-access MAF lists 17 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 12, Splice Site 2, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CATSPER1 | c.2019C>A p.S673R | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV100376098; called by muse, mutect2
- FBXO4 | c.605A>C p.E202A | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV55851930, COSV99715216; called by muse, mutect2, varscan2
- IL6R | c.1025A>G p.N342S | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV100690930; called by muse, mutect2
- KRT5 | c.1393G>A p.V465M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.619); catalogued as rs758969808, COSV52862027; called by muse, mutect2, varscan2
- ME3 | c.1131+1G>A p.X377_splice | Splice Site (SNP) | VAF 13/29 reads (45%) | catalogued as COSV100661023; called by muse, mutect2, varscan2
- MYBL1 | c.284A>G p.D95G | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101576573; called by muse, mutect2, varscan2
- PDLIM5 | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as COSV100524024, COSV58748810; called by muse, mutect2, varscan2
- RAD50 | c.1628A>G p.K543R | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs766041105, COSV99529206; called by muse, mutect2, varscan2
- RNF126 | c.759C>G p.D253E | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as COSV99293768; called by muse, varscan2
- SPTB | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as rs752995009, COSV67629801; called by muse, mutect2, varscan2
- TBC1D31 | c.1547T>C p.F516S | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99782961; called by muse, mutect2, varscan2
- TXK | c.523G>T p.V175F | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99972626; called by muse, mutect2, varscan2
- VPS8 | c.2785G>T p.D929Y (on ENST00000625842 / NM_001349294.1; = p.D927Y on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99802927; called by muse, varscan2
- WWC1 | c.1919+2T>C p.X640_splice | Splice Site (SNP) | VAF 10/22 reads (45%) | catalogued as COSV99515405; called by muse, mutect2, varscan2
- ZNF503 | c.1594T>A p.S532T | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100998021; called by muse, mutect2, varscan2
- TAF1L | c.75C>T p.S25= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV99645010; called by muse, mutect2, varscan2
- TGS1 | c.2532C>T p.D844= | Silent (SNP) | VAF 37/84 reads (44%) | catalogued as COSV99485530; called by muse, mutect2, varscan2
